Somatic mutation profile of tumor specimen TCGA-VS-A954-01A (aliquot TCGA-VS-A954-01A-11D-A387-09) from TCGA case TCGA-VS-A954, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIIB; Tumor grade: G2; Age at diagnosis: 67.1 years (24,498 days).
Specimen TCGA-VS-A954-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8629cd9c-eaf1-4f49-af7f-6682ab2b4ccb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-VS-A954-10A (Blood Derived Normal), aliquot TCGA-VS-A954-10A-01D-A38A-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/49786970-4312-4cea-b80a-37af156ea348

The open-access MAF lists 101 somatic variants for this specimen: 61 protein-altering or splice-affecting, 37 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 53, Silent 37, Nonsense Mutation 4, Intron 2, Splice Site 2, Frame Shift Del 2, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CAMK2B | c.328G>A p.E110K | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.933); catalogued as rs1554402092, COSV99322935; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADAM12 | c.1435G>T p.G479* | Nonsense Mutation (SNP) | VAF 4/9 reads (44%) | catalogued as COSV100900247; called by muse, mutect2
- ADGRA1 | c.35C>A p.S12Y | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.278); catalogued as COSV101658594; called by muse, mutect2, varscan2
- ARHGEF10 | c.2951G>C p.R984T (on ENST00000398564; = p.R959T on NM_014629.4) | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0.05); catalogued as COSV100034308; called by muse, mutect2, varscan2
- ATP10A | c.454G>C p.E152Q | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT tolerated (0.14); PolyPhen benign (0.144); catalogued as COSV100791076, COSV63517530; called by muse, mutect2, varscan2
- ATP6V1A | c.1849G>A p.D617N | Missense Mutation (SNP) | VAF 16/90 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.163); catalogued as COSV56364409, COSV99850015; called by muse, mutect2, varscan2
- BTBD3 | c.475G>A p.E159K | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.321); catalogued as rs1350086540, COSV54780700; called by muse, mutect2, varscan2
- CLUH | c.769G>A p.G257S (on ENST00000435359; = p.G295S on NM_015229.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1398823356, COSV101425704; called by muse, mutect2, varscan2
- CRAMP1 | c.3748C>T p.R1250C | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.938); catalogued as rs755030192, COSV50188901; called by muse, mutect2, varscan2
- DMXL2 | c.6871C>T p.Q2291* | Nonsense Mutation (SNP) | VAF 7/31 reads (23%) | catalogued as COSV99196116, COSV99196190; called by muse, mutect2, varscan2
- EBF2 | c.1138C>G p.L380V | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.148); catalogued as COSV101282138, COSV68777591; called by muse, mutect2, varscan2
- EPHA5 | c.1258G>A p.G420S | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.15); PolyPhen probably damaging (1); catalogued as rs370503988; called by muse, mutect2, varscan2
- FCGBP | c.6497C>T p.S2166L | Missense Mutation (SNP) | VAF 40/272 reads (15%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.562); catalogued as rs1383600985; called by muse, mutect2, varscan2
- FLG | c.6557C>T p.S2186F | Missense Mutation (SNP) | VAF 35/187 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.165); catalogued as COSV100911407; called by muse, mutect2, varscan2
- FNDC1 | c.2093G>A p.R698Q | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.007); catalogued as rs757886821, COSV99795445; called by muse, mutect2, varscan2
- GPNMB | c.1475C>G p.S492W (on ENST00000381990 / NM_001005340.2; = p.S480W on NM_002510.3) | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.879); catalogued as COSV51701879; called by muse, mutect2, varscan2
- HNRNPUL1 | c.1184C>T p.P395L | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.081); catalogued as rs1194508282, COSV54562555; called by muse, mutect2, varscan2
- IFT57 | c.585+1G>C p.X195_splice | Splice Site (SNP) | VAF 4/32 reads (13%) | catalogued as COSV99197350; called by muse, mutect2, varscan2
- IQCC | c.1331C>T p.S444F | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.106); catalogued as rs866842577, COSV99356478; called by muse, mutect2, varscan2
- KANK1 | c.3897+1G>A p.X1299_splice | Splice Site (SNP) | VAF 7/21 reads (33%) | catalogued as rs758108591, COSV66527195; called by muse, mutect2, varscan2
- KCNJ4 | c.1052G>A p.R351Q | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.713); catalogued as rs781279543, COSV57858924; called by muse, mutect2, varscan2
- LRRC56 | c.1609C>T p.P537S | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.006); catalogued as COSV99529888; called by muse, mutect2, varscan2
- MRGPRD | c.393C>G p.I131M | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.985); catalogued as COSV100482976; called by muse, mutect2, varscan2
- MRPS22 | c.559G>A p.E187K (on ENST00000310776 / NM_001363893.1; = p.E188K on NM_020191.4) | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100169033; called by muse, mutect2, varscan2
- MTMR7 | c.556C>T p.R186W | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as rs369466778; called by muse, mutect2, varscan2
- MUC16 | c.19295C>T p.S6432F | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT tolerated, low confidence (0.12); PolyPhen possibly damaging (0.905); catalogued as COSV67453173; called by muse, mutect2, varscan2
- NIPBL | c.5025C>A p.F1675L | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56942935, COSV99242640; called by muse, mutect2, varscan2
- NOP14 | c.2363A>G p.E788G | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100054499; called by muse, mutect2, varscan2
- NR3C1 | c.179G>C p.R60T | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.131); catalogued as COSV99196203; called by muse, mutect2, varscan2
- NRAP | c.49G>A p.E17K | Missense Mutation (SNP) | VAF 14/23 reads (61%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.977); catalogued as rs576211641, COSV100748663, COSV63489092; called by muse, mutect2, varscan2
- NUP155 | c.38C>G p.S13C | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.053); catalogued as COSV99192575; called by muse, mutect2, varscan2
- NVL | c.1234C>T p.R412* | Nonsense Mutation (SNP) | VAF 5/47 reads (11%) | catalogued as rs773133873, COSV55874920; called by muse, mutect2, varscan2
- OR2G6 | c.200C>T p.S67L | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs560459259, COSV100598091, COSV58573816; called by muse, mutect2, varscan2
- P3H2 | c.860G>A p.C287Y | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100077386; called by muse, mutect2, varscan2
- PAPPA | c.847C>G p.Q283E | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100073568; called by muse, mutect2, varscan2
- PAXIP1 | c.1448G>A p.R483H | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.23); catalogued as rs928291763, COSV68185974; called by muse, mutect2, varscan2
- PCDHGA8 | c.2008G>A p.E670K | Missense Mutation (SNP) | VAF 26/73 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.077); catalogued as COSV53940288; called by muse, mutect2, varscan2
- PCDHGB2 | c.191G>A p.R64Q | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.327); catalogued as COSV99535226; called by muse, mutect2, varscan2
- PCM1 | c.3398C>T p.S1133L | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.225); catalogued as COSV100278824, COSV100278962; called by muse, mutect2
- PNISR | c.1823G>A p.R608Q | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.5); catalogued as rs756564984, COSV65080110; called by muse, mutect2, varscan2
- PSMC1 | c.1118C>T p.T373M | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT tolerated (0.14); PolyPhen benign (0.047); catalogued as rs772023510, COSV99728275; called by muse, mutect2, varscan2
- PTK7 | c.2843C>T p.A948V | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT tolerated (0.17); PolyPhen benign (0.428); catalogued as COSV100030061; called by muse, mutect2, varscan2
- RIMS1 | c.2174C>T p.S725F | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV53439647, COSV53448834; called by muse, mutect2, varscan2
- RYR2 | c.11695G>C p.D3899H | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100769351; called by muse, mutect2, varscan2
- SACS | c.12848G>C p.R4283T | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.046); catalogued as COSV101207338, COSV66538592; called by muse, mutect2, varscan2
- SLC32A1 | c.134C>T p.A45V | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as COSV54145571; called by muse, mutect2, varscan2
- SOX14 | c.121C>T p.R41C | Missense Mutation (SNP) | VAF 27/105 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.758); catalogued as rs1490118665, COSV60162632; called by muse, mutect2, varscan2
- SOX30 | c.623G>T p.R208L | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as COSV99398292; called by muse, mutect2, varscan2
- STAG1 | c.2754G>C p.Q918H | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as COSV99365052; called by muse, mutect2, varscan2
- TTYH1 | c.1270G>A p.D424N | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.946); catalogued as rs768159304, COSV100001920; called by muse, mutect2, varscan2
- TUSC3 | c.258G>A p.M86I | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.019); catalogued as rs751192990, COSV101140992; called by muse, mutect2, varscan2
- UNC93B1 | c.1157C>T p.A386V | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT tolerated (0.27); PolyPhen benign (0.343); catalogued as COSV99916326; called by muse, mutect2, varscan2
- USP39 | c.721C>T p.Q241* | Nonsense Mutation (SNP) | VAF 7/23 reads (30%) | catalogued as COSV100083719; called by mutect2, varscan2
- ZFHX4 | c.454G>T p.A152S | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.34); PolyPhen benign (0.385); catalogued as COSV99261020; called by muse, mutect2, varscan2
- ZFHX4 | c.3067C>T p.H1023Y | Missense Mutation (SNP) | VAF 12/21 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99261024; called by muse, mutect2, varscan2
- ZNF559 | c.1489G>C p.E497Q | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT tolerated (0.31); PolyPhen benign (0.34); catalogued as COSV100416503; called by muse, mutect2, varscan2
- CBWD5 | c.1058G>A p.R353K (on ENST00000382405 / NM_001330668.1; = p.R305K on NM_001024916.3) | Missense Mutation (SNP) | VAF 31/347 reads (9%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.506); called by muse, mutect2
- CLTC | c.4137G>A p.M1379I | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT tolerated (0.63); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- COL19A1 | c.3002del p.G1001Afs*18 | Frame Shift Del (DEL) | VAF 13/35 reads (37%) | called by mutect2, pindel, varscan2
- GLI2 | c.1371G>T p.W457C (on ENST00000361492 / NM_001374353.1; = p.W474C on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- RBM11 | c.230del p.G77Efs*29 | Frame Shift Del (DEL) | VAF 12/44 reads (27%) | called by mutect2, pindel, varscan2
- ADAP1 | c.228C>T p.H76= | Silent (SNP) | VAF 18/46 reads (39%) | catalogued as rs1008760311, COSV56210807, COSV56216394; called by muse, mutect2, varscan2
- AGRN | c.4902G>A p.G1634= | Silent (SNP) | VAF 18/58 reads (31%) | catalogued as COSV101038728; called by muse, mutect2, varscan2
- AGRN | c.5046G>A p.Q1682= | Silent (SNP) | VAF 22/60 reads (37%) | catalogued as COSV101038729; called by muse, mutect2, varscan2
- ATP13A5 | c.3435C>T p.I1145= | Silent (SNP) | VAF 10/52 reads (19%) | catalogued as COSV99290636; called by muse, mutect2, varscan2
- CCR4 | c.675C>T p.I225= | Silent (SNP) | VAF 13/22 reads (59%) | catalogued as rs1188022395, COSV100447347; called by muse, mutect2, varscan2
- DOCK1 | c.4563G>A p.P1521= | Silent (SNP) | VAF 4/28 reads (14%) | catalogued as rs376719633; called by mutect2, varscan2
- EP300 | c.3147C>T p.F1049= | Silent (SNP) | VAF 9/40 reads (23%) | catalogued as COSV99608134; called by muse, mutect2, varscan2
- EPHA5 | c.1887T>C p.D629= | Silent (SNP) | VAF 14/32 reads (44%) | catalogued as COSV99897971; called by muse, mutect2, varscan2
- FAT2 | c.12123G>A p.R4041= | Silent (SNP) | VAF 14/42 reads (33%) | catalogued as COSV99942360; called by muse, mutect2, varscan2
- GLRB | c.1212A>G p.R404= | Silent (SNP) | VAF 7/22 reads (32%) | catalogued as COSV100029619; called by muse, mutect2, varscan2
- GMDS | c.630G>A p.E210= | Silent (SNP) | VAF 18/43 reads (42%) | catalogued as COSV101071628; called by muse, mutect2, varscan2
- H2BC14 | c.285C>T p.I95= | Silent (SNP) | VAF 22/66 reads (33%) | catalogued as COSV100297553; called by muse, mutect2, varscan2
- ITSN2 | c.5094G>A p.*1698= | Silent (SNP) | VAF 13/41 reads (32%) | catalogued as rs1383865430, COSV100743154, COSV61944058; called by muse, mutect2, varscan2
- KCNK15 | c.807C>T p.P269= | Silent (SNP) | VAF 4/11 reads (36%) | catalogued as rs1487469562, COSV100865101; called by muse, mutect2
- MRTFB | c.237G>A p.A79= | Silent (SNP) | VAF 12/34 reads (35%) | catalogued as rs756700929, COSV100370810, COSV57956644; called by muse, mutect2, varscan2
- MTMR14 | c.231G>A p.T77= | Silent (SNP) | VAF 7/62 reads (11%) | catalogued as rs377425419, COSV56003766; called by muse, mutect2, varscan2
- NAGLU | c.507C>T p.S169= | Silent (SNP) | VAF 16/38 reads (42%) | catalogued as rs1378009555, CD003098, CD113471, CD962094, COSV99864063; called by muse, mutect2, varscan2
- NCAM2 | c.2391G>A p.L797= | Silent (SNP) | VAF 20/55 reads (36%) | catalogued as COSV53082644; called by muse, mutect2, varscan2
- NCF4 | c.768G>A p.A256= | Silent (SNP) | VAF 20/55 reads (36%) | catalogued as rs766525712, COSV99957244; called by muse, mutect2, varscan2
- NCOR1 | c.2439C>T p.P813= | Silent (SNP) | VAF 18/42 reads (43%) | catalogued as COSV99249107; called by muse, mutect2, varscan2
- NIPA2 | c.687G>A p.V229= | Silent (SNP) | VAF 7/21 reads (33%) | catalogued as rs1348907760, COSV100488073; called by muse, mutect2, varscan2
- NLRP7 | c.972C>T p.F324= | Silent (SNP) | VAF 10/37 reads (27%) | catalogued as COSV60181799; called by muse, mutect2, varscan2
- NOTCH3 | c.714C>T p.D238= | Silent (SNP) | VAF 5/22 reads (23%) | catalogued as rs138307755; called by muse, mutect2, varscan2
- OR2T3 | c.717C>T p.H239= | Silent (SNP) | VAF 8/98 reads (8%) | called by muse, mutect2
- OR2T34 | c.717C>T p.R239= | Silent (SNP) | VAF 8/22 reads (36%) | catalogued as rs1192326432, COSV100170332; called by mutect2, varscan2
- OR5AK2 | c.399T>C p.T133= | Silent (SNP) | VAF 7/28 reads (25%) | catalogued as rs373245457; called by muse, mutect2, varscan2
- OR5B2 | c.511C>T p.L171= | Silent (SNP) | VAF 6/23 reads (26%) | catalogued as COSV100222839; called by muse, mutect2, varscan2
- PLCG1 | c.2235G>A p.P745= | Silent (SNP) | VAF 11/32 reads (34%) | catalogued as COSV99718712; called by muse, mutect2, varscan2
- PLPP7 | c.696C>T p.I232= | Silent (SNP) | VAF 30/37 reads (81%) | catalogued as rs752847529, COSV100953107; called by muse, mutect2, varscan2
- POMGNT2 | c.759G>A p.P253= | Silent (SNP) | VAF 5/12 reads (42%) | catalogued as rs981484756, COSV100768015; called by mutect2, varscan2
- RHOQ | c.24G>A p.L8= | Silent (SNP) | VAF 5/14 reads (36%) | catalogued as COSV99475734; called by muse, mutect2, varscan2
- SEC61A1 | c.543C>T p.L181= | Silent (SNP) | VAF 13/56 reads (23%) | catalogued as rs752828595, COSV54579441, COSV99684810; called by muse, mutect2, varscan2
- SRMS | c.1062G>C p.R354= | Silent (SNP) | VAF 9/38 reads (24%) | catalogued as COSV99420435; called by muse, mutect2, varscan2
- SULF2 | c.585C>T p.L195= | Silent (SNP) | VAF 7/32 reads (22%) | catalogued as rs756623773, COSV100737123; called by muse, mutect2, varscan2
- TOP2A | c.474G>A p.V158= | Silent (SNP) | VAF 10/24 reads (42%) | catalogued as COSV101396146; called by muse, mutect2, varscan2
- UBR4 | c.14367G>A p.R4789= | Silent (SNP) | VAF 8/38 reads (21%) | catalogued as COSV100920669; called by muse, mutect2
- ZBTB3 | c.1182C>T p.P394= | Silent (SNP) | VAF 4/11 reads (36%) | catalogued as rs761971879, COSV67360887; called by muse, mutect2, varscan2
- AL132655.6 | chr20:58840488 del GAGCCTGAGACCGCCCCCACCACT | 5'Flank (DEL) | VAF 22/93 reads (24%) | catalogued as rs747093000; called by mutect2, pindel, varscan2
- CNKSR3 | c.946-316C>T | Intron (SNP) | VAF 10/28 reads (36%) | called by muse, mutect2, varscan2
- MACF1 | c.15832-8238G>C | Intron (SNP) | VAF 13/90 reads (14%) | catalogued as COSV99243169; called by muse, mutect2, varscan2
